Somatic mutation profile of tumor specimen 0DT9NO from CCDI case PBCJFD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.1 years (1,118 days).
Specimen 0DT9NO: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3080104c-49a4-4400-b29d-86bd1a7f0b1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT9NB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/114ef55e-6a05-417a-9825-862ad6f3a8d0

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 429/466 reads (92%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.1732G>C p.G578R | Missense Mutation (SNP) | VAF 205/218 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52233726; called by muse, mutect2, varscan2
- PSD4 | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 372/407 reads (91%) | catalogued as COSV55530382; called by muse, mutect2, varscan2
- PXDNL | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 54/1096 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62483481, COSV99080565; called by muse, mutect2
- SPON1 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 26/750 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs34322893; called by muse, mutect2
- RASA1 | c.1086T>A p.Y362* | Nonsense Mutation (SNP) | VAF 163/188 reads (87%) | called by muse, mutect2, varscan2
- STAU2 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 78/764 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- TAAR2 | c.199T>C p.S67P (on ENST00000367931 / NM_001033080.1; = p.S22P on NM_014626.3) | Missense Mutation (SNP) | VAF 17/419 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KRT7 | c.966C>T p.I322= | Silent (SNP) | VAF 242/481 reads (50%) | catalogued as rs140473746; called by muse, mutect2, varscan2
- TBKBP1 | c.1293G>A p.P431= | Silent (SNP) | VAF 309/328 reads (94%) | catalogued as rs1421765425; called by muse, mutect2, varscan2
- ZNF518B | c.2184G>A p.P728= | Silent (SNP) | VAF 31/573 reads (5%) | catalogued as rs374035596; called by muse, mutect2
- GSC2 | c.*26C>T | 3'UTR (SNP) | VAF 194/201 reads (97%) | called by muse, mutect2, varscan2
- RRM2B | c.48+228C>T | Intron (SNP) | VAF 90/1124 reads (8%) | catalogued as rs752647130; called by muse, mutect2
- TGFB1I1 | c.889-91G>T | Intron (SNP) | VAF 5/104 reads (5%) | catalogued as rs1264823115; called by muse, mutect2
